Gene-level copy-number profile of tumor specimen HTMCP-03-06-02002-01B from CGCI case HTMCP-03-06-02002, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB1; Tumor grade: G3; Age at diagnosis: 62.8 years (22,934 days).
Specimen HTMCP-03-06-02002-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 8235d98d-6291-4a3c-be48-5a2ea6cb7fd0.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02002-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,247 have no estimate.
https://portal.gdc.cancer.gov/files/340ce24f-9b64-4964-a4f6-6a2dc5cbafaa

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 28; copy number 1: 1,786; copy number 2: 46,214; copy number 3: 5,115; copy number 4: 3,736; copy number 5: 831; copy number 6: 615; copy number 7: 42; copy number 8: 6; copy number 25: 2; copy number 88: 1.

Homozygous deletions (total copy number 0; autosomes only): 28 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:16,739,938–16,972,964, 11 genes (within-gene range 0–2): AL021920.3, CROCC, CROCCP4, RNU1-4, MST1L, BX284668.1, BX284668.3, MIR3675, BX284668.2, RNU1-5P, BX284668.5.
- chr1:16,895,980–16,904,776, 2 genes (within-gene range 0–2): RNU1-2, BX284668.6.
- chr6:29,887,294–29,929,232, 7 genes: AL645929.1, HLA-H, HLA-T, DDX39BP1, MCCD1P1, HCG4B, HLA-K.
- chr11:1,947,278–1,989,920, 2 genes: MRPL23, MRPL23-AS1.
- chr11:114,570,591–114,595,786, 2 genes: NXPE4, AC020549.2.
- chr13:57,173,453–57,204,799, 2 genes: PRR20FP, MTCO2P3.
- chr16:71,080,866–71,093,667, 1 gene (within-gene range 0–2): AC138625.2.
- chr21:8,701,461–8,701,562, 1 gene: CR381572.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 999 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,903,318–151,372,707, 77 genes, copy number 5 (broad region; genes not listed).
- chr1:153,500,463–156,933,094, 206 genes, copy number 5 (broad region; genes not listed).
- chr1:160,931,739–161,605,662, 48 genes, copy number 5 (within-gene range 4–5): AL354714.3, AL354714.1, AL354714.4, ITLN2, F11R, AL591806.2, GLRX5P2, TSTD1, USF1, ARHGAP30, NECTIN4, NECTIN4-AS1, KLHDC9, PFDN2, NIT1, DEDD, AL591806.1, UFC1, AL590714.1, USP21, PPOX, B4GALT3, ADAMTS4, NDUFS2, FCER1G, APOA2, TOMM40L, MIR5187, NR1I3, PCP4L1, MPZ, SDHC, CFAP126, AL592295.6, RRM2P2, AL592295.4, AL592295.5, RNU6-481P, AL592295.3, AL592295.1, AL592295.2, FCGR2A, AL590385.2, HSPA6, RPS23P10, FCGR3A, AL590385.1, FCGR2C.
- chr1:173,799,550–173,824,720, 1 gene, copy number 7 (within-gene range 4–7): CENPL.
- chr1:173,824,653–173,858,808, 1 gene, copy number 7: DARS2.
- chr1:241,916,123–241,999,098, 4 genes, copy number 5: RPL23AP20, BECN2, CFL1P4, MAP1LC3C.
- chr3:161,083,883–198,123,232, 642 genes, copy number 6–7 (broad region; genes not listed).
- chr6:33,299,694–33,339,495, 6 genes, copy number 5: TAPBP, ZBTB22, DAXX, SMIM40, SMIM40, MYL8P.
- chr9:63,974,762–64,440,180, 5 genes, copy number 8–25: AL163540.1, U6, ANKRD20A4P, RNU6-1193P, SNX18P9.
- chr9:64,765,054–64,765,535, 1 gene, copy number 88: IGKV1OR-2.
- chr9:64,817,870–64,836,341, 1 gene, copy number 7: AL359955.1.
- chr9:136,612,024–136,672,678, 4 genes, copy number 5: LINC01451, AL590226.1, EGFL7, MIR126.
- chr14:18,333,726–18,341,859, 1 gene, copy number 5: CR383658.1.
- chr17:78,146,353–78,166,177, 2 genes, copy number 7: C17orf99, EIF5AP2.

Autosomal genes at a single copy (total copy number 1): 1,786. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
